TCGA case TCGA-RR-A6KA — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: St. Joseph's Hospital AZ. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/225f3689-221d-4296-8472-d8c21eedaf8d

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Dead; Days to death: 191 days.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.1; Tissue or organ of origin: Frontal lobe; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 72.8 years (26,582 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 191 days; Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RR-A6KA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 100 mg.
  Slide TCGA-RR-A6KA-01A-02-TSB: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-RR-A6KA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RR-A6KA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Glioblastoma Multiforme (GBM); History lgg diagnosis of brain tissue: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Treatment outcome first course: Partial Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 191 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 191 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 191 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RR-A6KA-01A-21D-A33S-01): tumor purity 0.57, ploidy 2.06, whole-genome doublings 0.
